Somatic mutation profile of cancer-model specimen HCM-SANG-0315-C25-85A (3D Organoid; aliquot HCM-SANG-0315-C25-85A-01D-A78J-36), derived from the primary tumor of HCMI case HCM-SANG-0315-C25, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; Tumor grade: G2.
Specimen HCM-SANG-0315-C25-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cb035ffa-3dbe-49bf-b14e-326ab3fa604e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-SANG-0315-C25-10A (Blood Derived Normal), aliquot HCM-SANG-0315-C25-10A-01D-A78J-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fc090077-e29b-4489-a5fd-860f39e9a117

The open-access MAF lists 46 somatic variants for this specimen: 32 protein-altering or splice-affecting, 9 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 24, Silent 9, Frame Shift Del 3, In Frame Del 2, Splice Region 1, Intron 1, Splice Site 1, 5'UTR 1, RNA 1, 3'UTR 1, Nonsense Mutation 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>C p.G12R | Missense Mutation (SNP) | VAF 151/323 reads (47%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.497); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.742C>T p.R248W | Missense Mutation (SNP) | VAF 180/180 reads (100%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121912651, CM010465, CM900211, COSV52662035, COSV52797251, COSV53097881; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCB1 | c.2510C>A p.T837N | Missense Mutation (SNP) | VAF 196/421 reads (47%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.653); catalogued as COSV99714427; called by muse, mutect2, varscan2
- ADGRG2 | c.1048G>A p.V350M (on ENST00000379869 / NM_001079858.3; = p.V347M on NM_005756.4) | Missense Mutation (SNP) | VAF 26/73 reads (36%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as rs370180158; called by muse, mutect2, varscan2
- CDKN2A | c.22del p.S8Afs*18 | Frame Shift Del (DEL) | VAF 102/142 reads (72%) | catalogued as COSV100446643, COSV58714967; called by mutect2, pindel, varscan2
- CYP21A2 | c.1096C>T p.H366Y | Missense Mutation (SNP) | VAF 430/2022 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1330554738, CM042969, COSV100925719; called by muse, mutect2
- DIPK1C | c.325C>T p.R109C | Missense Mutation (SNP) | VAF 177/178 reads (99%) | SIFT deleterious (0); PolyPhen possibly damaging (0.714); catalogued as rs186260585; called by muse, mutect2, varscan2
- DMPK | c.496C>T p.R166W | Missense Mutation (SNP) | VAF 127/279 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs764428073; called by muse, mutect2, varscan2
- ERICH3 | c.1808G>A p.R603K | Missense Mutation (SNP) | VAF 161/319 reads (50%) | SIFT tolerated (0.22); PolyPhen benign (0.061); catalogued as rs1340052239; called by muse, mutect2, varscan2
- GABRB1 | c.1264G>A p.G422R | Missense Mutation (SNP) | VAF 124/274 reads (45%) | SIFT tolerated (0.69); PolyPhen benign (0.005); catalogued as rs748097369, COSV54984293; called by muse, mutect2, varscan2
- GRIA3 | c.997C>T p.R333W | Missense Mutation (SNP) | VAF 110/193 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99989435; called by muse, mutect2, varscan2
- HTR3A | c.656G>A p.R219Q | Missense Mutation (SNP) | VAF 235/450 reads (52%) | SIFT tolerated (0.74); PolyPhen benign (0.015); catalogued as rs745886965; called by muse, mutect2, varscan2
- LARS1 | c.2992-1G>C p.X998_splice (on ENST00000394434 / NM_020117.11; = p.X971_splice on NM_016460.3) | Splice Site (SNP) | VAF 116/224 reads (52%) | catalogued as COSV50978508; called by muse, mutect2, varscan2
- NBPF12 | c.1576C>G p.L526V | Missense Mutation (SNP) | VAF 110/444 reads (25%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.87); catalogued as rs1553886435; called by muse, varscan2
- NCKAP5 | c.5335G>A p.G1779S | Missense Mutation (SNP) | VAF 118/240 reads (49%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs777248110, COSV58475362; called by muse, mutect2
- RYR3 | c.4036G>A p.G1346R | Missense Mutation (SNP) | VAF 67/167 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1309424472, COSV66780694; called by muse, mutect2, varscan2
- SRL | c.38C>T p.S13L | Missense Mutation (SNP) | VAF 169/400 reads (42%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.097); catalogued as rs1470713580, COSV68422856; called by muse, mutect2, varscan2
- ABCA3 | c.125_139del p.L42_I46del | In Frame Del (DEL) | VAF 243/676 reads (36%) | called by mutect2, pindel, varscan2
- ADAM17 | c.623T>A p.L208H | Missense Mutation (SNP) | VAF 63/133 reads (47%) | SIFT tolerated (0.55); PolyPhen benign (0); called by muse, mutect2, varscan2
- ANXA4 | c.855_876del p.R286Mfs*47 | Frame Shift Del (DEL) | VAF 28/175 reads (16%) | called by mutect2, pindel
- CBX8 | c.853A>G p.I285V | Missense Mutation (SNP) | VAF 233/233 reads (100%) | SIFT tolerated (0.57); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DCAF1 | c.3277G>A p.E1093K | Missense Mutation (SNP) | VAF 111/208 reads (53%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.882); called by muse, mutect2, varscan2
- DCLK3 | c.1453G>A p.V485I | Missense Mutation (SNP) | VAF 97/169 reads (57%) | SIFT tolerated (0.05); PolyPhen benign (0.407); called by muse, mutect2, varscan2
- HECTD2 | c.2211C>A p.C737* | Nonsense Mutation (SNP) | VAF 48/113 reads (42%) | called by muse, mutect2, varscan2
- KCNK3 | c.901G>A p.A301T | Missense Mutation (SNP) | VAF 92/166 reads (55%) | SIFT tolerated (0.21); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- KLHL11 | c.96_104del p.S33_G35del | In Frame Del (DEL) | VAF 36/118 reads (31%) | called by mutect2, pindel, varscan2
- OR2T34 | c.368T>A p.M123K | Missense Mutation (SNP) | VAF 80/215 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- PYGO1 | c.1001_1020del p.H334Lfs*13 | Frame Shift Del (DEL) | VAF 103/244 reads (42%) | called by mutect2, pindel, varscan2
- REEP2 | c.233C>G p.S78C | Missense Mutation (SNP) | VAF 82/226 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.798); called by muse, mutect2, varscan2
- SORL1 | c.5000G>T p.G1667V | Missense Mutation (SNP) | VAF 112/243 reads (46%) | SIFT tolerated (0.15); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TTC4 | c.979-8T>C | Splice Region (SNP) | VAF 77/155 reads (50%) | called by muse, mutect2, varscan2
- ZNF729 | c.3302A>G p.K1101R | Missense Mutation (SNP) | VAF 207/438 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- BHLHE22 | c.327C>G p.G109= | Silent (SNP) | VAF 27/27 reads (100%) | called by muse, mutect2, varscan2
- CACNA1H | c.1329C>T p.N443= | Silent (SNP) | VAF 342/534 reads (64%) | catalogued as rs368405304; called by muse, mutect2
- MOV10 | c.2967G>A p.G989= | Silent (SNP) | VAF 65/142 reads (46%) | called by muse, mutect2, varscan2
- MYCBPAP | c.282C>T p.P94= | Silent (SNP) | VAF 247/517 reads (48%) | called by muse, mutect2, varscan2
- PRSS53 | c.432C>T p.C144= | Silent (SNP) | VAF 51/88 reads (58%) | called by muse, mutect2, varscan2
- PSMD2 | c.2064G>A p.R688= | Silent (SNP) | VAF 144/274 reads (53%) | catalogued as rs761740401; called by muse, mutect2, varscan2
- ROBO2 | c.2997G>A p.T999= | Silent (SNP) | VAF 120/303 reads (40%) | catalogued as rs898400879, COSV100167229; called by muse, mutect2, varscan2
- ZNF215 | c.1212G>A p.E404= | Silent (SNP) | VAF 66/136 reads (49%) | called by muse, mutect2, varscan2
- ZNF497 | c.921C>T p.C307= | Silent (SNP) | VAF 118/224 reads (53%) | called by muse, mutect2, varscan2
- LAPTM4B | c.-31_-30insGCTTGGAGCTCCAGCAGCT | 5'UTR (INS) | VAF 5/52 reads (10%) | called by pindel, varscan2*
- MYPN | c.*1392G>C | 3'UTR (SNP) | VAF 70/131 reads (53%) | catalogued as rs1014798278; called by muse, varscan2
- NNT | c.1445-1256_1445-1241del | Intron (DEL) | VAF 28/93 reads (30%) | called by mutect2, pindel
- PDZD7 | chr10:101015760 C>T | 3'Flank (SNP) | VAF 159/292 reads (54%) | catalogued as rs553462764; called by muse, mutect2, varscan2
- SPATA31C2 | n.2454T>C | RNA (SNP) | VAF 352/737 reads (48%) | catalogued as rs767427128; called by muse, mutect2, varscan2
